FM case AD2015 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/a1bb13b2-d214-4a84-9b8c-e460b24a2036

Female, 50.8 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the cervix uteri; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
